Somatic mutation profile of tumor specimen 0DQUA3 from CCDI case PBCERJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 11.9 years (4,343 days).
Specimen 0DQUA3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aa67fc0-45c8-4505-b367-34fd9a0cd25f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQUA4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32269528-e6bc-410e-a28c-691ca288d545

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2B | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 262/1593 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100313028; called by muse, varscan2
- C2CD5 | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 216/713 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as rs1360435594; called by muse, varscan2
- RGS12 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 296/720 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as rs201483642; called by muse, varscan2
- ABCG4 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 144/523 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, varscan2
- NVL | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 350/920 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- HSPG2 | c.4458C>T p.A1486= | Silent (SNP) | VAF 228/546 reads (42%) | catalogued as rs530009689, COSV101021513; called by muse, varscan2
- NTSR2 | c.927C>T p.C309= | Silent (SNP) | VAF 140/454 reads (31%) | catalogued as rs1317583305; called by muse, varscan2
- SLC6A1 | c.1182T>A p.I394= | Silent (SNP) | VAF 110/305 reads (36%) | called by muse, varscan2
- ABCB9 | c.602-61G>A | Intron (SNP) | VAF 88/208 reads (42%) | called by muse, varscan2
- CS | c.588+32G>C | Intron (SNP) | VAF 156/334 reads (47%) | called by muse, varscan2
- FAM219A | c.*81G>C | 3'UTR (SNP) | VAF 66/158 reads (42%) | called by muse, varscan2
- MAN2A2 | c.2719-80C>T | Intron (SNP) | VAF 40/108 reads (37%) | catalogued as rs955470563; called by muse, varscan2
